Somatic mutation profile of tumor specimen TCGA-EJ-A46F-01A (aliquot TCGA-EJ-A46F-01A-31D-A257-08) from TCGA case TCGA-EJ-A46F, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.9 years (21,160 days).
Specimen TCGA-EJ-A46F-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e20d3fc-b6c4-4922-b8e7-024054cf2d3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A46F-10A (Blood Derived Normal), aliquot TCGA-EJ-A46F-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e47e7753-114f-4959-9dac-ba4fec452f0e

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Nonsense Mutation 3, Splice Region 2, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VIPAS39 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 71/156 reads (46%) | catalogued as rs200370925, CM101901, COSV58938805; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID5B | c.757C>T p.R253C | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54416019; called by muse, mutect2, varscan2
- CENATAC | c.55G>C p.G19R | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.937); catalogued as COSV57722321; called by muse, mutect2, varscan2
- CFH | c.2918G>T p.C973F | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM045282, COSV66406641; called by muse, mutect2, varscan2
- CLSPN | c.1090G>A p.G364S | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as rs114727604, COSV52047928; called by muse, mutect2, varscan2
- CUBN | c.10008C>G p.Y3336* | Nonsense Mutation (SNP) | VAF 6/86 reads (7%) | catalogued as COSV64710132; called by muse, mutect2
- DOCK4 | c.2283T>A p.A761= | Splice Region (SNP) | VAF 6/18 reads (33%) | catalogued as rs1159223289, COSV70234319; called by muse, mutect2, varscan2
- DPYS | c.1492G>A p.A498T | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs368932527; called by muse, mutect2, varscan2
- EIF4A1 | c.798G>C p.L266F | Missense Mutation (SNP) | VAF 63/74 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs774180617, COSV51510170, COSV51510934; called by muse, mutect2, varscan2
- FAM81B | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.534); catalogued as rs370398727; called by muse, mutect2, varscan2
- FLG | c.4952G>A p.R1651K | Missense Mutation (SNP) | VAF 173/397 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.432); catalogued as COSV64238365; called by muse, mutect2, varscan2
- GAB2 | c.1990G>A p.V664M (on ENST00000361507 / NM_080491.3; = p.V626M on NM_012296.3) | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as rs781659629, COSV60866527; called by muse, mutect2, varscan2
- MPP1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV65728028, COSV65728091; called by muse, mutect2, varscan2
- MTMR3 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV60302479; called by muse, mutect2, varscan2
- MUC16 | c.29327C>G p.S9776* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | catalogued as COSV67452546; called by muse, varscan2
- MYBPH | c.1230G>A p.K410= | Splice Region (SNP) | VAF 13/32 reads (41%) | catalogued as COSV55141645; called by muse, mutect2, varscan2
- RASAL3 | c.283A>G p.N95D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV52992137; called by muse, mutect2, varscan2
- SP100 | c.2075A>G p.N692S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.177); catalogued as COSV50975218; called by muse, mutect2, varscan2
- SPTBN4 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212063873, COSV58943610; called by muse, mutect2, varscan2
- SYNE1 | c.6568G>A p.D2190N (on ENST00000367255 / NM_182961.4; = p.D2197N on NM_033071.3) | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs1291524487, COSV54929985; called by muse, mutect2, varscan2
- TMEM132B | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.021); catalogued as rs936695274, COSV54746271; called by muse, mutect2, varscan2
- TOP3B | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.57); catalogued as COSV64116704, COSV64118220; called by muse, mutect2, varscan2
- TVP23C | c.743G>T p.W248L | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV56668620; called by muse, mutect2, varscan2
- ARHGEF26 | c.2052del p.L685Sfs*24 | Frame Shift Del (DEL) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- ITPR2 | c.6839del p.F2280Sfs*15 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- RAPGEF6 | c.608_610del p.S203_L204delinsI | In Frame Del (DEL) | VAF 29/83 reads (35%) | called by mutect2, pindel, varscan2
- BTBD2 | c.1317C>T p.G439= | Silent (SNP) | VAF 50/63 reads (79%) | catalogued as rs766740895, COSV55307870, COSV99724764; called by muse, mutect2, varscan2
- DOCK10 | c.3207A>C p.R1069= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV51358328; called by muse, mutect2
- LRFN5 | c.909G>A p.R303= | Silent (SNP) | VAF 43/91 reads (47%) | catalogued as rs751479194, COSV53247219; called by muse, mutect2, varscan2
- MUC17 | c.9108A>T p.I3036= | Silent (SNP) | VAF 256/498 reads (51%) | catalogued as COSV60282751, COSV60300911; called by muse, mutect2, varscan2
- PTX3 | c.60G>A p.S20= | Silent (SNP) | VAF 68/132 reads (52%) | catalogued as COSV55821307; called by muse, mutect2, varscan2
- SACS | c.5490G>A p.L1830= | Silent (SNP) | VAF 65/146 reads (45%) | catalogued as COSV66536339; called by muse, mutect2, varscan2
- SLC5A5 | c.1593C>T p.Y531= | Silent (SNP) | VAF 58/146 reads (40%) | catalogued as rs121909177, CM981847; called by muse, mutect2, varscan2
